Surgical pathology report (de-identified scan), TCGA case TCGA-A4-8098, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-8098-01A (Primary Tumor).

[page 1 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - B.) RENAL MASS, RIGHT, AND BASE OF RIGHT RENAL MASS, RESECTION,
- RENAL CELL CARCINOMA, PAPILLARY VARIANT, TYPE I.
- Tumor measures 3.0 cm in greatest dimension.
- Tumor confined to kidney.
- No lymphovascular or perineural invasion identified.
- MARGINS: INDETERMINATE (SEE COMMENT).
- LYMPH NODES: NONE IDENTIFIED.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Renal cell carcinoma, papillary variant, type I.

Primary tumor: pT1a.

Regional lymph nodes: pNX.

Distant metastasis: pMX.

Margin status: Indeterminate.

Pathologic stage: I.

Lymphovascular invasion: Not identified.

Perineural invasion: Not identified.

COMMENT: Immunohistochemical studies show that the tumor is positive for PAX-8, CD10, racemase, and EMA. It is negative for inhibin, CK5/6, p63, CK7, CK20, CD117, synaptophysin, and chromogranin. The staining patterns support the given diagnosis. All the immunohistochemical studies were interpreted here at [REDACTED]

[REDACTED] The inhibin stain is the only stain which was performed outside, at [REDACTED]

Due to the fragmented nature of the specimen, the margin status cannot be accurately determined by pathologic examination. Both specimen B and the three cauterized fragments of renal tissue (in cassette A8) are free of tumor. I am not certain whether the combination of specimen B and the tissue in A8 is the complete surgical margin and whether or not it was fully overlying the pieces of specimen A that have tumor at the edge. Clinical correlation regarding the margin status is suggested.

Kidney Tumor Staging Information

[page 2 of 3]
FINAL SURGICAL PATHOLOGY REPORT

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook

Procedure:	Partial nephrectomy.
Specimen type:	Portion of kidney.
Specimen laterality:	Right.
Tumor Features:	
Tumor size:	3.0 cm in greatest dimension.
Tumor focality:	Unifocal.
Histologic type:	Renal cell carcinoma, papillary variant, type I.
Histologic grade (Fuhrman nuclear grade):	N/A.
Sarcomatoid features:	Not identified.
Macroscopic extent of tumor:	Confined to kidney.
Microscopic tumor extension:	Confined to kidney.
Lymph Nodes:	None identified.
Margin evaluation:	Indeterminate.
Pathologic tumor staging descriptors:	
Primary tumor:	pT1a.
Regional lymph nodes:	pNX.
Distant metastasis:	pMX.
Margin status:	Indeterminate.
Pathologic stage:	I.
Histologic findings in non-neoplastic kidney:	None.
Additional histologic findings:	None.
Comment:	N/A.

[page 3 of 3]
FINAL SURGICAL PATHOLOGY REPORT

- A. Mass;right renal mass
- B. Mass;base of right renal mass

Clinical History/Operative Dx:
Right renal mass

Gross Description:

A. The specimen is labeled right renal mass and is received without fixative. It consists of an ovoid fragment of renal tissue which measures 3 x 2.3 x 1.3 cm. The apparent cortical surface has a slightly irregular contour and is dull red. The opposite surface (deep surface) shows a rim of prominent cautery artifact and approximately two-thirds of the deep surface has a torn and disrupted appearance with friable tumor present. The cauterized portion of the deep margin of this specimen is inked blue. On serial sectioning of this specimen, there is a partially cavitory and very friable tumor mass present which measures 2.5 x 1.7 x 1.4 cm. Also in the specimen container are multiple fragments of friable tan to light brown tumor which are 3 cm in aggregate and multiple fragments of lobulated fatty tissue measuring 7 x 5 x 2 cm in aggregate and weighing 39 grams. The specimen container also has three additional fragments of heavily cauterized renal tissue which vary from 1.1 x 0.7 x 0.3 cm to 1.7 x 0.9 x 0.4 cm. Each of these fragments has focally cauterized surface. Sections of the adipose tissue reveal no grossly identifiable tumor. Representative sections of the tumor are obtained for research purposes. The entire resection of kidney tissue is sequentially submitted in cassettes A1-A6. Representative sections of the separately submitted friable tumor are submitted in cassette A7. The smaller fragments of cauterized renal tissue are submitted in cassette A8 and representative sections of the separately submitted adipose tissue are submitted in cassette A9.

B. The specimen is labeled base of right renal (tumor) mass and is received in formalin. It consists of five fragments of dark brown to nearly black, heavily cauterized tissue which are 1 cm in aggregate. The largest intact fragment measures 0.7 x 0.4 x 0.2 cm. The tissue is entirely submitted in cassette B1.

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Source: NCI Genomic Data Commons file 4f04a68b-f1bc-474d-bd2b-c4154baa5aaa (TCGA-A4-8098.2E11A542-5E27-4F63-A801-81B755BD7486.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).